Somatic mutation profile of tumor specimen MMRF_2113_1_BM_CD138pos (aliquot MMRF_2113_1_BM_CD138pos_T1_KHS5U_L08824) from MMRF case MMRF_2113, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.9 years (26,277 days).
Specimen MMRF_2113_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eb898f5-c393-4b24-86e9-99586500b6f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2113_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2113_1_PB_Whole_C3_KHS5U_L08767; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1c9a7cd-a809-45da-b6b0-32fa9208a277

The open-access MAF lists 98 somatic variants for this specimen: 31 protein-altering or splice-affecting, 15 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 29, Silent 15, Intron 11, 5'UTR 5, 3'Flank 3, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDS1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs530030554; called by muse, mutect2, varscan2
- CKMT1B | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 109/229 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765473721, COSV55852482; called by muse, mutect2, varscan2
- CTCF | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs755800964, COSV99064259; called by muse, mutect2, varscan2
- GIGYF2 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65247145; called by muse, mutect2, varscan2
- IFI30 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1237378099; called by muse, mutect2, varscan2
- IGLV4-3 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs369551255; called by muse, mutect2, varscan2
- KDM3B | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1334033128; called by muse, mutect2, varscan2
- LACTBL1 | c.11G>A p.R4Q (on ENST00000618559; = p.R33Q on NM_001289974.2) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1019863762; called by muse, mutect2, varscan2
- LAMA1 | c.2891C>T p.T964M | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs758300021, COSV67543778; called by muse, mutect2, varscan2
- MTMR7 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs374185031; called by muse, mutect2, varscan2
- PKP3 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs368034548; called by muse, mutect2, varscan2
- PLCB4 | c.3502G>T p.D1168Y (on ENST00000278655 / NM_182797.3; = p.G1180V on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99596088; called by muse, mutect2, varscan2
- RAVER2 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53810515; called by muse, mutect2, varscan2
- SBK2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV60015521; called by muse, mutect2, varscan2
- SNTA1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369968387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBXT | c.255C>A p.N85K | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as rs1403111221, COSV99752905; called by muse, mutect2, varscan2
- AIFM3 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- BEND2 | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL9A1 | c.461dup p.F155Ifs*23 | Frame Shift Ins (INS) | VAF 76/194 reads (39%) | called by mutect2, pindel, varscan2
- FBXO32 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCD1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- IGLV3-10 | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KDM3B | c.326del p.G109Afs*12 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- RAB32 | c.193A>C p.K65Q | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RIT1 | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SEC14L1 | c.2111C>G p.S704C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TENM4 | c.2062A>G p.N688D | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRAP1 | c.883T>A p.L295M | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ZSCAN5B | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZSCAN5C | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZZEF1 | c.7573A>C p.K2525Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ABCA12 | c.6966T>C p.S2322= (on ENST00000272895 / NM_173076.3; = p.S2004= on NM_015657.3) | Silent (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- BCLAF1 | c.486G>A p.Q162= | Silent (SNP) | VAF 48/235 reads (20%) | called by muse, mutect2, varscan2
- DSCAML1 | c.1770C>T p.G590= (on ENST00000321322; = p.G530= on NM_020693.4) | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- FSCN2 | c.352C>T p.L118= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- GRIN2C | c.1188T>G p.P396= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- HMCN1 | c.14184C>T p.S4728= | Silent (SNP) | VAF 118/189 reads (62%) | catalogued as rs373228905; called by muse, mutect2, varscan2
- IGHD3-22 | c.7C>T p.L3= | Silent (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- IPCEF1 | c.630T>C p.F210= | Silent (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- MYB | c.333T>C p.G111= | Silent (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- NDN | c.208C>T p.L70= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1419086864; called by muse, mutect2, varscan2
- NOVA2 | c.849T>A p.L283= | Silent (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- OBSCN | c.18585G>A p.A6195= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs770466904; called by muse, varscan2
- OR2Z1 | c.342G>A p.L114= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs151009943; called by muse, mutect2, varscan2
- RLBP1 | c.159C>T p.N53= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1173055601; called by muse, mutect2, varscan2
- UBXN4 | c.984T>C p.D328= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- ABCC9 | chr12:21800891 A>G | 3'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- ALDH1A1 | c.*305T>A | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- ARSA | c.466-50C>G | Intron (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- ATP5MGL | c.*134T>G | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- BZW1 | c.*34G>T | 3'UTR (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- BZW1 | c.*35A>T | 3'UTR (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- CDC20B | c.-44C>G | 5'UTR (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- COL18A1 | c.3598-125A>C | Intron (SNP) | VAF 23/25 reads (92%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+720G>A | Intron (SNP) | VAF 13/73 reads (18%) | catalogued as rs375979815; called by muse, mutect2, varscan2
- EIF2A | c.*35A>T | 3'UTR (SNP) | VAF 60/256 reads (23%) | called by muse, mutect2, varscan2
- FABP1 | c.334-496G>A | Intron (SNP) | VAF 10/29 reads (34%) | catalogued as rs527966789; called by muse, mutect2, varscan2
- FGF5 | c.*1546T>C | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- GMNC | c.268-33G>T | Intron (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- GNA14 | c.*107T>A | 3'UTR (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- GRID1 | c.*914G>A | 3'UTR (SNP) | VAF 71/227 reads (31%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*710T>G | 3'UTR (SNP) | VAF 43/73 reads (59%) | called by muse, mutect2, varscan2
- IFITM10 | c.*1130C>T | 3'UTR (SNP) | VAF 110/191 reads (58%) | catalogued as rs1378594082; called by muse, mutect2, varscan2
- IGSF23 | c.125+4409C>T | Intron (SNP) | VAF 28/63 reads (44%) | catalogued as rs148464272; called by muse, mutect2, varscan2
- IPMK | c.*712A>C | 3'UTR (SNP) | VAF 91/201 reads (45%) | called by muse, mutect2, varscan2
- ITPR1 | c.*1006T>C | 3'UTR (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- ITPRID1 | chr7:31653681 G>A | 3'Flank (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- JMJD8 | chr16:684338 C>G | 5'Flank (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- KATNBL1 | c.*81T>C | 3'UTR (SNP) | VAF 45/109 reads (41%) | called by muse, varscan2
- KATNBL1 | c.*15T>C | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, varscan2
- KRAS | c.*1411A>T | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- KRTAP1-5 | c.*13T>A | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- LRRC8B | c.*304A>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- LTB | c.163-145G>A | Intron (SNP) | VAF 68/136 reads (50%) | catalogued as rs140984421, COSV53000853; called by muse, mutect2, varscan2
- MOB1B | c.*3094A>G | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- MRPL53 | c.92+19T>G | Intron (SNP) | VAF 84/178 reads (47%) | called by muse, mutect2, varscan2
- NAA50 | c.*1484C>T | 3'UTR (SNP) | VAF 19/44 reads (43%) | catalogued as rs146980042; called by muse, mutect2, varscan2
- NAPEPLD | c.*37A>T | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- NEGR1 | c.*3925G>A | 3'UTR (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- NXN | c.*588A>G | 3'UTR (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- PAK5 | c.*715C>T | 3'UTR (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- PLPP2 | c.-49C>T | 5'UTR (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- PLPPR4 | c.*1958G>A | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- POFUT2 | c.*238G>A | 3'UTR (SNP) | VAF 47/53 reads (89%) | called by muse, mutect2, varscan2
- PRKCH | c.-131G>A | 5'UTR (SNP) | VAF 19/22 reads (86%) | called by muse, mutect2, varscan2
- ROBO2 | c.1850-60T>G | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as COSV59895378; called by muse, mutect2, varscan2
- RPS23 | c.*1002G>A | 3'UTR (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- SAMD1 | c.*276G>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- SSPOP | n.13819G>A | RNA (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2509+12G>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- TMEM33 | c.615-160A>G | Intron (SNP) | VAF 15/48 reads (31%) | catalogued as rs534014417; called by muse, mutect2, varscan2
- TMOD2 | c.*1436T>C | 3'UTR (SNP) | VAF 33/61 reads (54%) | catalogued as rs973977975; called by muse, mutect2, varscan2
- TOR1AIP1 | c.-27C>G | 5'UTR (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- TP63 | c.*2215T>G | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- TRERF1 | c.-184C>T | 5'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- TRIB1 | c.*1196C>A | 3'UTR (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- TTC29 | chr4:146706948 C>T | 3'Flank (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- Z83844.2 | chr22:37639497 G>A | 5'Flank (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
